Somatic mutation profile of tumor specimen MP2PRT-PAUTEG-TMP1-A (aliquot MP2PRT-PAUTEG-TMP1-A-1-0-D-A835-36) from MP2PRT case MP2PRT-PAUTEG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.1 years (2,594 days).
Specimen MP2PRT-PAUTEG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0249b1a-3e66-4347-80d9-cdc93d179380.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUTEG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUTEG-NB1-A-1-0-D-A835-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccd10274-2e64-457e-98b5-141cce82c6df

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.174C>G p.N58K | Missense Mutation (SNP) | VAF 73/367 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs397507506, CM030492, COSV61010398, COSV61010683; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 33/661 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by muse, mutect2
- ADAMDEC1 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 163/508 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.163); catalogued as rs200134300; called by muse, varscan2
- ERG | c.1108G>A p.D370N (on ENST00000398919 / NM_001243428.1; = p.D346N on NM_004449.4) | Missense Mutation (SNP) | VAF 258/1347 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV55727362; called by muse, varscan2
- PCSK5 | c.5308C>T p.R1770* | Nonsense Mutation (SNP) | VAF 177/573 reads (31%) | catalogued as rs775532268; called by muse, varscan2
- PNLIPRP2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 147/747 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs1198140788, COSV53942794; called by muse, mutect2, varscan2
- SPAG16 | c.1886C>T p.T629M | Missense Mutation (SNP) | VAF 67/338 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs979132676; called by muse, mutect2, varscan2
- TMEM132C | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 124/590 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.391); catalogued as rs1024188659, COSV70660677; called by muse, varscan2
- DNAH9 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 243/954 reads (25%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SAMD1 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 146/428 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- SH2B2 | c.2012A>C p.Q671P | Missense Mutation (SNP) | VAF 120/558 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- AC100868.1 | c.1932G>T p.V644= | Silent (SNP) | VAF 253/678 reads (37%) | called by muse, mutect2, varscan2
- EDA2R | c.888C>T p.S296= | Silent (SNP) | VAF 156/618 reads (25%) | called by muse, mutect2, varscan2
- FOXF2 | c.729C>T p.Y243= | Silent (SNP) | VAF 254/1610 reads (16%) | called by muse, mutect2, varscan2
- PLXNA4 | c.3597G>A p.L1199= | Silent (SNP) | VAF 192/562 reads (34%) | called by muse, varscan2
- SCRN1 | chr7:29990196 C>T | 5'Flank (SNP) | VAF 26/519 reads (5%) | catalogued as rs1266373416; called by muse, mutect2
